Surgical pathology report (de-identified scan), TCGA case TCGA-CG-5727, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Indivumed, specimen TCGA-CG-5727-01A (Primary Tumor).

Findings and diagnosis in response to the q

In the case of I., this involves, firstly, a free lymph node in the stated area and secondly, in relation to the stomach and specifically to the area said to be temporal, an invasive gastric carcinoma of the intestinal type with infiltration of the muscularis as far as the serosa (p T 3).

There are free resection margins in the mucosal area, free resection margins in the ligature region, free lymph nodes, and also free omental tissue.

II. and III., embedded separately, are free lymph nodes.

Tumor classification:

ICDO-DA-M 8140/3

p T 3, L 1, p N 0.

The mucosal resection margins were tumor-free.

Source: NCI Genomic Data Commons file 1900f9cd-400e-49c7-bab6-56d3c7eb6d17 (TCGA-CG-5727.E8D2B419-7F3D-4E0A-A126-9BEDFC75A0B9.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).